Somatic mutation profile of cancer-model specimen HCM-BROD-0111-C25-85A (3D Organoid, passage 5; aliquot HCM-BROD-0111-C25-85A-01D-A786-36), derived from the metastatic tumor of HCMI case HCM-BROD-0111-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 67.5 years (24,655 days).
Specimen HCM-BROD-0111-C25-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 5.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8053fbe4-32bc-4d2b-9809-8a3eb085a2d6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0111-C25-10A (Blood Derived Normal), aliquot HCM-BROD-0111-C25-10A-01D-A786-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2047c46b-04ed-4d71-bc8a-1f3b6508ed46

The open-access MAF lists 134 somatic variants for this specimen: 93 protein-altering or splice-affecting, 32 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 74, Silent 32, Nonsense Mutation 6, Splice Site 4, Frame Shift Ins 4, 5'UTR 3, Intron 2, Frame Shift Del 2, RNA 2, 3'UTR 2, In Frame Del 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HADHB | c.209+1G>A p.X70_splice | Splice Site (SNP) | VAF 128/399 reads (32%) | catalogued as rs113112630, CS116217; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 359/564 reads (64%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.636del p.R213Dfs*34 | Frame Shift Del (DEL) | VAF 253/356 reads (71%) | catalogued as rs864309495, CD011205, COSV52729299; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ADGRF5 | c.712C>T p.P238S | Missense Mutation (SNP) | VAF 28/104 reads (27%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs746853446; called by muse, mutect2, varscan2
- ADGRV1 | c.13732G>A p.G4578R | Missense Mutation (SNP) | VAF 56/190 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs550190828, COSV67989870; called by muse, mutect2, varscan2
- BACE1 | c.766C>T p.R256W | Missense Mutation (SNP) | VAF 48/268 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs770251178, COSV57286496; called by muse, mutect2
- BHMT2 | c.1036C>A p.L346M | Missense Mutation (SNP) | VAF 114/217 reads (53%) | SIFT deleterious (0.02); PolyPhen benign (0.139); catalogued as COSV54874503; called by muse, mutect2, varscan2
- CDHR4 | c.754G>A p.G252S | Missense Mutation (SNP) | VAF 107/240 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs554908956; called by muse, mutect2, varscan2
- CGB3 | c.262C>T p.R88W | Missense Mutation (SNP) | VAF 231/987 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.305); catalogued as rs1490123740; called by muse, mutect2, varscan2
- COL20A1 | c.762dup p.N255Efs*66 | Frame Shift Ins (INS) | VAF 54/273 reads (20%) | catalogued as rs749207634; called by mutect2, varscan2
- COL22A1 | c.3610-1G>T p.X1204_splice | Splice Site (SNP) | VAF 74/640 reads (12%) | catalogued as COSV100278657; called by muse, mutect2, varscan2
- COL3A1 | c.2987G>T p.G996V | Missense Mutation (SNP) | VAF 231/370 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM000351, COSV58585097; called by muse, mutect2, varscan2
- DCAF4L2 | c.994G>A p.V332M | Missense Mutation (SNP) | VAF 162/217 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs747432904, COSV60479126, COSV60479633; called by muse, mutect2, varscan2
- DISP3 | c.139C>T p.R47W | Missense Mutation (SNP) | VAF 72/239 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.727); catalogued as rs373256766; called by muse, mutect2, varscan2
- DOCK3 | c.4801G>T p.E1601* | Nonsense Mutation (SNP) | VAF 67/195 reads (34%) | catalogued as COSV56550087; called by muse, mutect2, varscan2
- DPH2 | c.373C>T p.R125C | Missense Mutation (SNP) | VAF 142/318 reads (45%) | SIFT deleterious (0.05); PolyPhen benign (0.417); catalogued as rs772653759, COSV52543764, COSV99356286; called by muse, mutect2, varscan2
- DYNC1H1 | c.8851G>A p.A2951T | Missense Mutation (SNP) | VAF 603/605 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV64138205; called by muse, mutect2, varscan2
- ECRG4 | c.301A>T p.I101F | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.075); catalogued as COSV53001013; called by muse, mutect2
- EPHA3 | c.2234G>A p.R745Q | Missense Mutation (SNP) | VAF 109/212 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs756739935, COSV60693553; called by muse, mutect2, varscan2
- EPHA8 | c.1070G>A p.R357H | Missense Mutation (SNP) | VAF 102/262 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as rs373378884, COSV99385162; called by muse, mutect2, varscan2
- FAM135B | c.3688C>T p.R1230W | Missense Mutation (SNP) | VAF 99/819 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1173973435, COSV52722766; called by muse, mutect2, varscan2
- FBN3 | c.8156G>A p.R2719Q | Missense Mutation (SNP) | VAF 52/105 reads (50%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as rs144078033; called by muse, mutect2, varscan2
- FLT4 | c.1307C>T p.S436L | Missense Mutation (SNP) | VAF 119/377 reads (32%) | SIFT tolerated (0.3); PolyPhen benign (0.013); catalogued as rs1221447329; called by muse, mutect2, varscan2
- GABRB3 | c.229G>A p.E77K | Missense Mutation (SNP) | VAF 128/390 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.44); catalogued as COSV54683394; called by muse, mutect2, varscan2
- GART | c.2324G>A p.R775H | Missense Mutation (SNP) | VAF 42/138 reads (30%) | SIFT tolerated (0.43); PolyPhen benign (0.031); catalogued as rs148170440; called by muse, mutect2, varscan2
- GEM | c.527G>A p.R176H | Missense Mutation (SNP) | VAF 166/695 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs759240105, COSV52596840; called by muse, mutect2, varscan2
- GPAM | c.982C>T p.R328W | Missense Mutation (SNP) | VAF 126/387 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs776750785, COSV62080618; called by muse, mutect2, varscan2
- GPR78 | c.557C>T p.A186V | Missense Mutation (SNP) | VAF 115/307 reads (37%) | SIFT tolerated (0.91); PolyPhen benign (0.045); catalogued as rs370418169; called by muse, mutect2, varscan2
- GRXCR1 | c.186G>T p.Q62H | Missense Mutation (SNP) | VAF 110/342 reads (32%) | SIFT tolerated (0.54); PolyPhen benign (0.359); catalogued as COSV67672052; called by muse, mutect2, varscan2
- HSPB8 | c.539G>A p.S180N | Missense Mutation (SNP) | VAF 239/700 reads (34%) | SIFT tolerated (0.29); PolyPhen benign (0.062); catalogued as COSV56138503; called by muse, mutect2, varscan2
- HYDIN | c.10145G>A p.R3382H | Missense Mutation (SNP) | VAF 109/288 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs756180570; called by muse, mutect2, varscan2
- INPP5A | c.506C>T p.T169M | Missense Mutation (SNP) | VAF 68/256 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.562); catalogued as rs1398291918; called by muse, mutect2, varscan2
- KIF22 | c.1710G>T p.E570D | Missense Mutation (SNP) | VAF 125/183 reads (68%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV99361362; called by muse, mutect2, varscan2
- MARK3 | c.2185C>T p.R729W (on ENST00000429436 / NM_001128918.3; = p.R705W on NM_002376.6) | Missense Mutation (SNP) | VAF 239/344 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs775415963, COSV53507686; called by muse, mutect2, varscan2
- MFSD9 | c.977G>A p.S326N | Missense Mutation (SNP) | VAF 73/310 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1306172216; called by muse, mutect2, varscan2
- MUC16 | c.41863G>A p.V13955I | Missense Mutation (SNP) | VAF 66/138 reads (48%) | SIFT tolerated, low confidence (0.21); PolyPhen possibly damaging (0.855); catalogued as rs756887648, COSV66695154; called by muse, mutect2, varscan2
- NPY1R | c.715A>C p.K239Q | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT tolerated (0.31); PolyPhen benign (0.084); catalogued as COSV56714895; called by muse, mutect2, varscan2
- NUP210 | c.3140G>T p.R1047L | Missense Mutation (SNP) | VAF 49/108 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV54410271; called by muse, mutect2, varscan2
- OR2G6 | c.391C>T p.R131C | Missense Mutation (SNP) | VAF 326/421 reads (77%) | SIFT deleterious (0); PolyPhen benign (0.394); catalogued as rs371117704; called by muse, mutect2, varscan2
- OR2M2 | c.347C>T p.A116V | Missense Mutation (SNP) | VAF 239/327 reads (73%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as rs1191377246; called by muse, mutect2, varscan2
- PLPP3 | c.722C>T p.T241M | Missense Mutation (SNP) | VAF 53/110 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs772751531, COSV64840648; called by muse, mutect2, varscan2
- PRDM16 | c.2350C>T p.P784S | Missense Mutation (SNP) | VAF 59/167 reads (35%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.986); catalogued as rs183595422; called by muse, mutect2, varscan2
- RFX3 | c.1813A>C p.S605R | Missense Mutation (SNP) | VAF 70/137 reads (51%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.89); catalogued as COSV100174541; called by muse, mutect2, varscan2
- RIPK4 | c.1804C>T p.R602C (on ENST00000352483; = p.R554C on NM_020639.3) | Missense Mutation (SNP) | VAF 141/259 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs552168720, COSV60190812; called by muse, mutect2, varscan2
- RP1 | c.506C>A p.A169E | Missense Mutation (SNP) | VAF 161/668 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.04); catalogued as COSV55119519; called by muse, mutect2, varscan2
- SIGLEC10 | c.38-1G>T p.X13_splice | Splice Site (SNP) | VAF 64/202 reads (32%) | catalogued as COSV59486447; called by muse, mutect2, varscan2
- SMOC2 | c.1279C>T p.R427C (on ENST00000356284 / NM_001166412.2; = p.R438C on NM_022138.3) | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.425); catalogued as rs368210259; called by muse, mutect2, varscan2
- TPSAB1 | c.601G>A p.D201N | Missense Mutation (SNP) | VAF 75/221 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1354523313; called by muse, mutect2, varscan2
- TRIM51GP | c.365G>A p.R122Q | Missense Mutation (SNP) | VAF 210/334 reads (63%) | SIFT tolerated (0.57); PolyPhen benign (0.031); catalogued as rs764888298; called by muse, varscan2
- UBE4B | c.1306C>T p.R436* (on ENST00000343090 / NM_001105562.3; = p.R307* on NM_006048.5) | Nonsense Mutation (SNP) | VAF 38/121 reads (31%) | catalogued as COSV53527591, COSV53529594; called by muse, mutect2, varscan2
- ZBTB16 | c.1883C>A p.S628* | Nonsense Mutation (SNP) | VAF 167/490 reads (34%) | catalogued as COSV60097743; called by muse, mutect2, varscan2
- ZFP2 | c.1097G>A p.R366Q | Missense Mutation (SNP) | VAF 146/229 reads (64%) | SIFT tolerated (0.1); PolyPhen benign (0.147); catalogued as rs778074289, COSV63726982; called by muse, mutect2, varscan2
- ZNF615 | c.1858G>A p.G620R | Missense Mutation (SNP) | VAF 78/272 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.966); catalogued as COSV100944029; called by muse, mutect2, varscan2
- ZSCAN1 | c.1081G>A p.V361I | Missense Mutation (SNP) | VAF 80/215 reads (37%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs369547013; called by muse, mutect2, varscan2
- ACVR2A | c.1181T>C p.L394P | Missense Mutation (SNP) | VAF 92/147 reads (63%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AGXT | c.686_688del p.K229del | In Frame Del (DEL) | VAF 86/328 reads (26%) | called by pindel, varscan2
- ANKRD9 | c.91dup p.R31Pfs*44 | Frame Shift Ins (INS) | VAF 79/347 reads (23%) | called by mutect2, pindel, varscan2
- ARHGEF40 | c.682G>A p.G228R | Missense Mutation (SNP) | VAF 36/116 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); called by muse, mutect2
- CD300LF | c.367G>C p.V123L | Missense Mutation (SNP) | VAF 54/87 reads (62%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.712); called by muse, mutect2
- CEP152 | c.655G>C p.E219Q | Missense Mutation (SNP) | VAF 196/278 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- CEP192 | c.6043A>C p.S2015R | Missense Mutation (SNP) | VAF 55/101 reads (54%) | SIFT deleterious (0); PolyPhen benign (0.391); called by muse, mutect2, varscan2
- CHRNB3 | c.662C>A p.P221H | Missense Mutation (SNP) | VAF 70/130 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CLDN18 | c.-3_6del | Translation Start Site (DEL) | VAF 38/222 reads (17%) | called by pindel, varscan2
- CLOCK | c.1862A>G p.H621R | Missense Mutation (SNP) | VAF 11/228 reads (5%) | SIFT tolerated (0.24); PolyPhen benign (0.035); called by muse, mutect2
- CMYA5 | c.2560C>T p.H854Y | Missense Mutation (SNP) | VAF 79/213 reads (37%) | SIFT tolerated (0.43); PolyPhen benign (0.439); called by muse, mutect2, varscan2
- DNAH12 | c.9266A>G p.Q3089R (on ENST00000351747; = p.Q3957R on NM_001366028.2) | Missense Mutation (SNP) | VAF 62/160 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- FOXRED1 | c.848A>T p.E283V | Missense Mutation (SNP) | VAF 193/592 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- GPRIN1 | c.550A>T p.K184* | Nonsense Mutation (SNP) | VAF 121/175 reads (69%) | called by muse, mutect2, varscan2
- GTF2H3 | c.592_593del p.S198Rfs*10 | Frame Shift Del (DEL) | VAF 23/72 reads (32%) | called by mutect2, pindel, varscan2
- HRNR | c.5140A>G p.S1714G | Missense Mutation (SNP) | VAF 139/3322 reads (4%) | SIFT tolerated (0.77); PolyPhen benign (0.007); called by muse, mutect2
- ITSN2 | c.351T>G p.F117L | Missense Mutation (SNP) | VAF 31/88 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.079); called by muse, varscan2
- KDM2B | c.622A>G p.K208E | Missense Mutation (SNP) | VAF 9/116 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); called by muse, mutect2
- KDM3B | c.1086_1089dup p.G364Kfs*10 | Frame Shift Ins (INS) | VAF 80/354 reads (23%) | called by pindel, varscan2
- NPAS2 | c.989A>G p.Y330C | Missense Mutation (SNP) | VAF 40/229 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR4C15 | c.1037A>T p.E346V (on ENST00000314644; = p.E292V on NM_001001920.2) | Missense Mutation (SNP) | VAF 56/157 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- P2RX5 | c.574A>T p.I192L | Missense Mutation (SNP) | VAF 336/337 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.92); called by muse, mutect2, varscan2
- PCDH10 | c.995A>T p.D332V | Missense Mutation (SNP) | VAF 101/246 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PCDH18 | c.445A>G p.S149G | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); called by muse, mutect2, varscan2
- PRDM13 | c.599C>T p.A200V | Missense Mutation (SNP) | VAF 91/211 reads (43%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- RIN3 | c.85G>T p.E29* | Nonsense Mutation (SNP) | VAF 181/531 reads (34%) | called by muse, mutect2, varscan2
- RUFY2 | c.1276A>G p.K426E | Missense Mutation (SNP) | VAF 58/175 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- SCML4 | c.298A>G p.I100V | Missense Mutation (SNP) | VAF 61/114 reads (54%) | SIFT tolerated (0.98); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SEC31A | c.2692C>T p.P898S (on ENST00000355196 / NM_001318120.1; = p.P859S on NM_016211.4) | Missense Mutation (SNP) | VAF 67/208 reads (32%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.73); called by muse, mutect2, varscan2
- SETD3 | c.149A>G p.Y50C | Missense Mutation (SNP) | VAF 216/216 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- SLC9C1 | c.2989dup p.M997Nfs*21 | Frame Shift Ins (INS) | VAF 24/123 reads (20%) | called by mutect2, pindel, varscan2
- TFDP2 | c.883_884+2del p.X295_splice (on ENST00000489671 / NM_001178139.2; = p.X235_splice on NM_006286.5) | Splice Site (DEL) | VAF 27/113 reads (24%) | called by mutect2, pindel, varscan2
- TFPI2 | c.460+8C>T | Splice Region (SNP) | VAF 46/139 reads (33%) | called by muse, mutect2, varscan2
- TMEM204 | c.532C>A p.L178M | Missense Mutation (SNP) | VAF 144/486 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.76); called by muse, mutect2, varscan2
- TRIM51GP | c.280G>A p.G94R | Missense Mutation (SNP) | VAF 114/370 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.166); called by muse, varscan2
- TTC23L | c.142G>T p.E48* | Nonsense Mutation (SNP) | VAF 47/148 reads (32%) | called by muse, mutect2, varscan2
- TTC26 | c.1122A>T p.Q374H | Missense Mutation (SNP) | VAF 47/133 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.598); called by muse, mutect2, varscan2
- ZFHX4 | c.2345T>C p.L782P | Missense Mutation (SNP) | VAF 234/325 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF516 | c.1914C>A p.D638E | Missense Mutation (SNP) | VAF 221/1172 reads (19%) | SIFT tolerated (0.74); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ABCA12 | c.147A>G p.P49= | Silent (SNP) | VAF 66/200 reads (33%) | called by muse, mutect2, varscan2
- ANKRD65 | c.1113C>T p.A371= | Silent (SNP) | VAF 95/278 reads (34%) | called by muse, mutect2, varscan2
- AOAH | c.33G>A p.A11= | Silent (SNP) | VAF 200/604 reads (33%) | catalogued as rs771387514; called by muse, mutect2, varscan2
- CDHR1 | c.984G>A p.A328= | Silent (SNP) | VAF 121/417 reads (29%) | catalogued as rs368242294; called by muse, mutect2, varscan2
- CEACAM18 | c.498C>A p.I166= | Silent (SNP) | VAF 323/560 reads (58%) | called by muse, mutect2
- CEP164 | c.1431C>T p.H477= | Silent (SNP) | VAF 60/199 reads (30%) | catalogued as rs539441637; called by muse, mutect2, varscan2
- CFAP221 | c.2145C>T p.P715= | Silent (SNP) | VAF 71/276 reads (26%) | catalogued as rs201824397; called by muse, mutect2, varscan2
- CFAP43 | c.4842G>A p.L1614= | Silent (SNP) | VAF 44/166 reads (27%) | called by muse, mutect2, varscan2
- CHST15 | c.726C>T p.H242= | Silent (SNP) | VAF 173/280 reads (62%) | catalogued as COSV60560241; called by muse, mutect2, varscan2
- DLGAP3 | c.825G>A p.A275= | Silent (SNP) | VAF 77/136 reads (57%) | catalogued as rs756223853; called by muse, mutect2, varscan2
- EPHA4 | c.2709G>A p.L903= | Silent (SNP) | VAF 146/241 reads (61%) | called by muse, mutect2, varscan2
- FAT3 | c.10155G>A p.R3385= | Silent (SNP) | VAF 36/151 reads (24%) | called by muse, mutect2, varscan2
- FBXL7 | c.381C>T p.S127= | Silent (SNP) | VAF 117/407 reads (29%) | catalogued as rs1161314652, COSV61648724; called by muse, mutect2, varscan2
- FGF23 | c.573C>T p.N191= | Silent (SNP) | VAF 61/170 reads (36%) | catalogued as rs886042161; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HOXA2 | c.348C>T p.A116= | Silent (SNP) | VAF 86/638 reads (13%) | catalogued as COSV56067502; called by mutect2, varscan2
- KIF18B | c.1566C>T p.L522= (on ENST00000593135 / NM_001265577.2; = p.L534= on NM_001264573.2) | Silent (SNP) | VAF 172/566 reads (30%) | called by muse, mutect2, varscan2
- LRRC53 | c.393C>T p.S131= | Silent (SNP) | VAF 69/140 reads (49%) | called by muse, mutect2, varscan2
- LY9 | c.1395T>A p.L465= | Silent (SNP) | VAF 74/329 reads (22%) | called by muse, mutect2, varscan2
- MIS18BP1 | c.898C>T p.L300= | Silent (SNP) | VAF 81/261 reads (31%) | called by muse, mutect2, varscan2
- MYCBP2 | c.8595A>G p.S2865= (on ENST00000357337; = p.S2903= on NM_015057.5) | Silent (SNP) | VAF 41/250 reads (16%) | called by muse, mutect2, varscan2
- MYO15A | c.7716C>T p.P2572= | Silent (SNP) | VAF 339/339 reads (100%) | catalogued as COSV99234688; called by muse, mutect2, varscan2
- NLRC5 | c.4453C>T p.L1485= | Silent (SNP) | VAF 101/338 reads (30%) | called by muse, mutect2, varscan2
- NPR3 | c.1371G>A p.L457= | Silent (SNP) | VAF 108/177 reads (61%) | catalogued as COSV54087544; called by muse, mutect2, varscan2
- OGDHL | c.918C>A p.A306= | Silent (SNP) | VAF 231/369 reads (63%) | called by muse, mutect2, varscan2
- PLA2G4C | c.228G>A p.T76= | Silent (SNP) | VAF 197/437 reads (45%) | catalogued as rs763858960, COSV100843917; called by muse, mutect2, varscan2
- PNMA3 | c.93C>A p.G31= | Silent (SNP) | VAF 137/137 reads (100%) | catalogued as rs200483739, COSV64722508; called by muse, mutect2, varscan2
- TECPR2 | c.2907C>T p.G969= | Silent (SNP) | VAF 30/84 reads (36%) | called by muse, mutect2, varscan2
- TMC6 | c.1692G>A p.T564= | Silent (SNP) | VAF 162/565 reads (29%) | catalogued as rs772083222, COSV59810016; called by muse, mutect2, varscan2
- TMEM178B | c.399T>C p.C133= | Silent (SNP) | VAF 74/251 reads (29%) | called by muse, mutect2, varscan2
- ULK1 | c.900C>T p.S300= | Silent (SNP) | VAF 250/250 reads (100%) | catalogued as rs571147302, COSV58854749; called by muse, mutect2, varscan2
- VWC2 | c.210C>T p.G70= | Silent (SNP) | VAF 72/505 reads (14%) | called by muse, mutect2, varscan2
- ZDBF2 | c.1224T>C p.F408= | Silent (SNP) | VAF 32/105 reads (30%) | called by muse, mutect2, varscan2
- CHMP3 | c.-4C>T | 5'UTR (SNP) | VAF 135/219 reads (62%) | catalogued as rs767527182, COSV99806800; called by muse, mutect2, varscan2
- CLEC10A | c.*22C>T | 3'UTR (SNP) | VAF 42/42 reads (100%) | catalogued as rs375775825; called by muse, mutect2, varscan2
- ECM2 | c.-110T>C | 5'UTR (SNP) | VAF 7/203 reads (3%) | called by muse, mutect2
- FXYD6-FXYD2 | c.259+3378G>A | Intron (SNP) | VAF 128/189 reads (68%) | called by muse, mutect2, varscan2
- PGR | c.2646+19C>T | Intron (SNP) | VAF 36/114 reads (32%) | called by muse, mutect2
- PREP | c.-115C>G | 5'UTR (SNP) | VAF 101/101 reads (100%) | catalogued as rs766719326; called by muse, mutect2, varscan2
- SECTM1 | c.*37C>T | 3'UTR (SNP) | VAF 85/286 reads (30%) | called by muse, mutect2, varscan2
- SLC22A17 | n.451C>T | RNA (SNP) | VAF 119/192 reads (62%) | catalogued as rs1053874000; called by muse, mutect2, varscan2
- SNORD116-6 | n.84G>A | RNA (SNP) | VAF 74/296 reads (25%) | catalogued as rs756590960; called by muse, mutect2, varscan2
